Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A145, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A145-01A (Primary Tumor).

105 003
Infantry, Chest Cancer, No.
8506/3 6w 11/22/10
Site: breast, NOS 050.9

page 1 / 2

Department of Cancer Pathology

Examination: Histopathological examination

Examination No.: 1

Patient: PESEL: Age: Gender: F

Material: Multiple organ resection – right breast
Unit in charge
Physician in charge:
Material collected on: Material received on:
Expected time of examination: up to 8 working days
Clinical diagnosis: Cancer of the right breast.

Examination performed on:

Macroscopic description:

Right breast, sized 18.3 x 18.8 x 4.2 cm, removed without axillary tissues and with a skin flap of 14.6 x 7.1 cm.
Weight 580 g.

Tumour sized 1.6 x 1.2 x 1.8 cm on the boundary of outer quadrants, placed 5.2 cm from the outer edge, 1.2 cm from the base and 0.8 cm from the skin.

Status after core needle biopsy (test No.

Microscopic description:

Carcinoma ductale - NHG2 (3 + 2+1:2 mitoses/ 10 HPF, visual area diameter 0.55 mm),
papilloma intraductale mamillae.
Glandular tissue showing parenchyma atrophy.

Examination result:

Including test No. anc

Carcinoma ductale invasum mammarum dextrae.

Metastases carcinomatosae in lymphonodo axillae (No I/VII).

(NHG2, pT1c, pN1a) INVASIVE DUCTAL CARCINOMA OF THE RIGHT BREAST

ONE METASTATIC AXILLARY LYMPH NODE

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 10% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Score = 2+, verification by the FISH method recommended.

Compliance validated by:

Significant Discrepancy		

Source: NCI Genomic Data Commons file ac351848-b2c1-4294-b813-a3c231dd8f42 (TCGA-D8-A145.1D26CB97-536A-4D10-A593-73C3A846BB13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).